Somatic mutation profile of tumor specimen TCGA-ET-A39O-01A (aliquot TCGA-ET-A39O-01A-11D-A19J-08) from TCGA case TCGA-ET-A39O, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 39.1 years (14,295 days).
Specimen TCGA-ET-A39O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfbf41df-d164-4cb2-9956-96224a85b9c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A39O-10A (Blood Derived Normal), aliquot TCGA-ET-A39O-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3c0d9e7-56fa-457c-8103-20f24380727f

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK11A | c.1360C>G p.L454V (on ENST00000378633 / NM_001313896.2; = p.L451V on NM_024011.4) | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV52307899; called by muse, mutect2, varscan2
- DSE | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59066234; called by muse, mutect2, varscan2
- MST1 | c.724G>C p.G242R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.091); catalogued as COSV56535568; called by muse, varscan2
- PLK2 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV57108899; called by muse, mutect2
- TBC1D2 | c.2635C>T p.R879W (on ENST00000465784 / NM_001267571.2; = p.R868W on NM_018421.4) | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1329668029, COSV59784779; called by muse, mutect2
- DCAF5 | c.1083C>T p.S361= | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as COSV58461809; called by muse, mutect2, varscan2
- GALNT7 | c.174A>G p.G58= | Silent (SNP) | VAF 5/95 reads (5%) | catalogued as COSV53932862; called by muse, mutect2
- MYBBP1A | c.3483C>T p.T1161= | Silent (SNP) | VAF 16/170 reads (9%) | catalogued as COSV54600845; called by muse, mutect2
- TOR1AIP1 | c.1747T>C p.L583= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as rs974924579, COSV54870884; called by muse, mutect2
